Gene-level copy-number profile of tumor specimen TCGA-WJ-A86L-01A from TCGA case TCGA-WJ-A86L, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.5 years (25,018 days).
Specimen TCGA-WJ-A86L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.5ffe5273-88f8-4952-9ead-33f8b3f5cc30.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WJ-A86L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9b1695ec-b461-4c70-904c-181d2b4c5174

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,241; copy number 2: 49,244; copy number 3: 5,265; copy number 4: 69; copy number 5: 990; copy number 6: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WJ-A86L-01A-12D-A38W-01): tumor purity 0.94, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:30,773,464–30,774,732, 1 gene: KRT18P66.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 996 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–168,376,876, 860 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:168,401,483–168,407,274, 1 gene, copy number 5: AL022100.2.
- chr1:215,630,026–215,630,117, 1 gene, copy number 5: SNORD116.
- chr3:172,425,850–172,604,006, 6 genes, copy number 6: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1.
- chr3:188,941,715–189,325,304, 3 genes, copy number 5 (within-gene range 3–5): TPRG1-AS1, TPRG1, AC009319.1.
- chr13:108,596,152–114,337,626, 121 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:68,591,796–68,955,392, 4 genes, copy number 5 (within-gene range 3–5): LINC01482, AC011591.2, AC011591.1, ABCA8.

Autosomal genes at a single copy (total copy number 1): 4,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
